Somatic mutation profile of tumor specimen TCGA-ZJ-AAXI-01A (aliquot TCGA-ZJ-AAXI-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.1 years (24,497 days).
Specimen TCGA-ZJ-AAXI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88b41250-e8c9-4aaa-a387-5d3d778ee9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXI-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXI-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68c1f8bf-a831-46b7-95be-dc47ebe5f0d8

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 46, Silent 20, Nonsense Mutation 6, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1804C>T p.R602* (on ENST00000399959; = p.R603* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs886041705, COSV101302335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 34/41 reads (83%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS18 | c.3588C>G p.H1196Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV51400457, COSV99271867, COSV99271979; called by muse, mutect2, varscan2
- ADCY5 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV59194770; called by muse, mutect2
- ADGRA3 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs928853508, COSV51561936; called by muse, mutect2, varscan2
- CADPS | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200699296, COSV51871986; called by mutect2, varscan2
- CD209 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1311874163, COSV52654281, COSV52655029; called by muse, mutect2
- CFP | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1444150137, COSV55951178; called by muse, mutect2
- CHAMP1 | c.2356C>T p.H786Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100778770; called by muse, mutect2, varscan2
- CLUH | c.786G>A p.Q262= (on ENST00000435359; = p.Q300= on NM_015229.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/57 reads (19%) | catalogued as COSV101425706; called by muse, mutect2, varscan2
- CNTLN | c.3722T>A p.M1241K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99263575; called by muse, mutect2, varscan2
- COL19A1 | c.358T>A p.W120R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100505955; called by muse, mutect2, varscan2
- COL21A1 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs202026963; called by muse, mutect2, varscan2
- CYB561 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100669095; called by muse, mutect2, varscan2
- DENND2A | c.2435C>T p.S812L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1227560734, COSV99325933; called by muse, mutect2, varscan2
- DSEL | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as COSV100025508; called by muse, mutect2, varscan2
- DYNLL1 | c.140A>T p.D47V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99655550; called by muse, mutect2, varscan2
- EIPR1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV101181927; called by muse, mutect2, varscan2
- EPB41L4B | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101000482; called by muse, mutect2
- EPS15 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV100869491; called by muse, mutect2, varscan2
- F8 | c.5069A>G p.E1690G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782655522, COSV64280380; called by muse, mutect2, varscan2
- FBXW11 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV51613436; called by muse, mutect2, varscan2
- GOSR1 | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV99853615; called by muse, mutect2
- GPR6 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV99254240; called by muse, mutect2, varscan2
- GUCY1B1 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV100025475; called by muse, mutect2
- HELLS | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99491939; called by muse, mutect2
- JAG1 | c.1422C>G p.I474M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99652690; called by muse, mutect2, varscan2
- KANSL1 | c.2122A>G p.R708G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99294340; called by muse, mutect2, varscan2
- KCND2 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100474901; called by muse, mutect2, varscan2
- KLHL40 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772187214, COSV99825429; called by muse, varscan2
- LATS1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV53586418; called by muse, mutect2, varscan2
- MED12 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100377204; called by muse, mutect2, varscan2
- MYH14 | c.2224C>T p.R742W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747057989, COSV51829606; called by muse, mutect2, varscan2
- NIN | c.4482G>A p.M1494I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99812851; called by muse, mutect2
- OR1A2 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.519); catalogued as COSV101126346, COSV67936273; called by muse, mutect2, varscan2
- OR52N5 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100399658; called by muse, mutect2
- PASK | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs766475442, COSV99299070; called by muse, mutect2, varscan2
- PHIP | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.939); catalogued as COSV99243797; called by muse, mutect2, varscan2
- PRPF6 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1291421051, COSV99411779; called by muse, mutect2, varscan2
- PTEN | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1554893808, CM110124, COSV64297332, COSV64308587, COSV64311451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPF1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV101035407; called by muse, mutect2, varscan2
- SCN8A | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV100633624; called by muse, mutect2
- SLC5A12 | c.15C>G p.N5K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54825482, COSV99744753; called by muse, mutect2, varscan2
- SPAG17 | c.5840C>T p.T1947I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100308661; called by muse, mutect2, varscan2
- SVIL | c.5227G>C p.D1743H (on ENST00000355867 / NM_021738.3; = p.D1317H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs762707894, COSV100881182; called by muse, mutect2, varscan2
- TMEM243 | c.356G>C p.*119Sext*19 | Nonstop Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as rs754107238, COSV99991329; called by muse, mutect2, varscan2
- TUT7 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV99462818; called by muse, mutect2, varscan2
- UBQLNL | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100974221; called by muse, mutect2, varscan2
- UNC93B1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV99916328; called by muse, mutect2, varscan2
- USP15 | c.1291G>A p.D431N (on ENST00000280377 / NM_001351159.2; = p.D402N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); catalogued as COSV99739114; called by muse, mutect2
- VAX2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs781910150, COSV52265668, COSV99313406; called by muse, mutect2, varscan2
- WWC2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100968257; called by muse, mutect2
- ZNF654 | c.2627C>T p.S876L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.061); catalogued as COSV100525675; called by muse, mutect2, varscan2
- AC131160.1 | c.1095C>G p.V365= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100590605; called by muse, mutect2, varscan2
- AOX1 | c.2316C>T p.Y772= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs1181052241, COSV65980288; called by muse, mutect2, varscan2
- BTBD11 | c.1341C>T p.H447= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs377331056, COSV99775302; called by muse, mutect2, varscan2
- CASP8AP2 | c.738A>G p.G246= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99386933; called by muse, mutect2, varscan2
- CHD5 | c.1659C>A p.P553= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV52425923; called by muse, mutect2, varscan2
- CHST8 | c.105G>A p.T35= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs143467252; called by muse, mutect2
- COL26A1 | c.1251C>T p.P417= (on ENST00000313669 / NM_001278563.3; = p.P415= on NM_133457.4) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1300390944, COSV58123703; called by muse, mutect2, varscan2
- CTPS1 | c.1665C>T p.L555= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- CYP2C9 | c.681G>A p.P227= | Silent (SNP) | VAF 42/197 reads (21%) | catalogued as rs772651628, COSV53249824; called by muse, mutect2, varscan2
- DELE1 | c.876C>T p.G292= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV52007307; called by muse, mutect2, varscan2
- IFI35 | c.30C>T p.H10= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs373816024; called by muse, mutect2, varscan2
- KCNF1 | c.1407G>A p.K469= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99705661; called by muse, mutect2, varscan2
- LMTK2 | c.4497C>T p.D1499= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs771250772, COSV51992312; called by muse, mutect2, varscan2
- PHACTR3 | c.768C>T p.F256= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100732427; called by muse, mutect2
- PLPPR5 | c.90C>T p.F30= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1421516068, COSV54174508; called by muse, mutect2
- PLXNA3 | c.963C>T p.F321= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs143354413, COSV100859903; called by muse, mutect2, varscan2
- PRKD1 | c.1608C>T p.I536= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100119871; called by muse, mutect2, varscan2
- PRKD1 | c.867G>A p.K289= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100119873; called by muse, mutect2, varscan2
- RDH16 | c.363C>T p.P121= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100660086; called by muse, mutect2, varscan2
- ULK2 | c.3045G>T p.V1015= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100860724; called by muse, mutect2, varscan2
